Somatic mutation profile of tumor specimen C3N-01414-04 (aliquot CPT0105600009) from CPTAC case C3N-01414, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 58.1 years (21,232 days).
Specimen C3N-01414-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06f646e0-57d5-4cf4-bbfa-31f0b229045e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01414-31 (Blood Derived Normal), aliquot CPT0108040002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3626e21a-7f8c-43e3-bae3-007f98d95da0

The open-access MAF lists 685 somatic variants for this specimen: 463 protein-altering or splice-affecting, 128 silent, 94 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 395, Silent 128, Intron 48, Nonsense Mutation 27, RNA 18, Frame Shift Del 14, Splice Site 13, 3'UTR 13, 5'Flank 10, Splice Region 8, 5'UTR 4, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHM | c.130G>T p.G44* | Nonsense Mutation (SNP) | VAF 54/104 reads (52%) | catalogued as rs886041175, CM021966; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 99/368 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1933C>A p.L645I | Missense Mutation (SNP) | VAF 71/290 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100229293; called by muse, mutect2, varscan2
- ABCA4 | c.5110G>T p.E1704* | Nonsense Mutation (SNP) | VAF 33/263 reads (13%) | catalogued as CD109660; called by muse, mutect2, varscan2
- ACLY | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs574241105; called by muse, mutect2, varscan2
- ACRV1 | c.299C>A p.A100E | Missense Mutation (SNP) | VAF 97/422 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.22); catalogued as COSV59754953; called by muse, mutect2, varscan2
- ACSM2B | c.1156G>C p.A386P | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV61659752; called by muse, mutect2, varscan2
- ACTC1 | c.482T>C p.V161A | Missense Mutation (SNP) | VAF 89/318 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.928); catalogued as rs1060502824; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AFDN | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.075); catalogued as rs1180121039, COSV60039134; called by muse, mutect2, varscan2
- AHNAK2 | c.11610A>T p.K3870N | Missense Mutation (SNP) | VAF 70/330 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as COSV60915788; called by muse, mutect2, varscan2
- AIRE | c.538G>T p.G180W | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52392405; called by muse, mutect2, varscan2
- APOB | c.7505C>A p.S2502* | Nonsense Mutation (SNP) | VAF 141/414 reads (34%) | catalogued as CM075985; called by muse, mutect2, varscan2
- ARL14 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs749857278; called by muse, mutect2, varscan2
- ARSA | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.97); catalogued as rs1407391133; called by muse, mutect2
- ASB17 | c.468G>C p.Q156H | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52411422; called by muse, mutect2, varscan2
- ASPRV1 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs554895120, COSV57229151; called by muse, mutect2, varscan2
- BACH2 | c.1978G>T p.A660S | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV57611600; called by muse, mutect2, varscan2
- BGN | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368783683, COSV59036896; called by muse, mutect2, varscan2
- BOD1L1 | c.1607G>T p.R536M | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1198053124; called by muse, mutect2, varscan2
- CCKBR | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV58101781; called by muse, mutect2
- CDH22 | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1255677683, COSV64836649; called by mutect2, varscan2
- CEACAM1 | c.375A>G p.I125M | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.677); catalogued as rs772794650; called by muse, mutect2, varscan2
- CEP192 | c.3772G>T p.A1258S | Missense Mutation (SNP) | VAF 63/263 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV58068558; called by muse, mutect2, varscan2
- CLCN4 | c.304G>C p.V102L | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV101073866; called by muse, mutect2, varscan2
- CLTCL1 | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs782573395, COSV54239486; called by muse, mutect2, varscan2
- COL15A1 | c.3230C>A p.P1077H | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as rs1211405731; called by muse, mutect2, varscan2
- COLEC12 | c.1492G>A p.G498S | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs747133472; called by muse, varscan2
- CPAMD8 | c.2675A>T p.K892M (on ENST00000651564; = p.K845M on NM_015692.5) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV71597447; called by muse, mutect2, varscan2
- CRB1 | c.1687A>T p.S563C | Missense Mutation (SNP) | VAF 97/540 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM155277; called by muse, mutect2, varscan2
- CRLF1 | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100679006, COSV62260985; called by muse, mutect2
- CUBN | c.9349C>A p.R3117S | Missense Mutation (SNP) | VAF 95/444 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV64729645; called by muse, mutect2, varscan2
- CUBN | c.7009G>T p.G2337W | Missense Mutation (SNP) | VAF 67/312 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100912416; called by muse, mutect2, varscan2
- DAO | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.967); catalogued as COSV57321923; called by muse, mutect2, varscan2
- DAXX | c.788G>T p.R263L | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56469008; called by muse, mutect2
- DDC | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 61/459 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63563602; called by muse, mutect2, varscan2
- DDHD1 | c.1653A>G p.L551= (on ENST00000323669; = p.L748= on NM_030637.3) | Splice Region (SNP) | VAF 34/136 reads (25%) | catalogued as COSV100079984; called by muse, varscan2
- DMXL1 | c.6768G>T p.Q2256H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100224565; called by muse, mutect2, varscan2
- DNAH10 | c.7712G>T p.G2571V (on ENST00000409039; = p.G2510V on NM_207437.3) | Missense Mutation (SNP) | VAF 49/247 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101292152; called by muse, mutect2, varscan2
- DNMT3A | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs761056829; called by muse, mutect2, varscan2
- DOCK2 | c.3442C>A p.Q1148K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs759770667; called by muse, mutect2, varscan2
- DOK3 | c.1152G>T p.W384C | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as COSV57252962; called by mutect2, varscan2
- DOP1B | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs778476083; called by muse, mutect2, varscan2
- DUSP22 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 12/148 reads (8%) | catalogued as COSV100739334; called by muse, mutect2
- EBF1 | c.1515C>A p.F505L | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.313); catalogued as COSV58189607; called by muse, mutect2, varscan2
- EIF2D | c.889A>G p.M297V | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs781933639; called by muse, mutect2
- ENTHD1 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs769284855; called by muse, varscan2
- ERI3 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as COSV64833792; called by muse, mutect2, varscan2
- ERICH6B | c.1050+1G>T p.X350_splice | Splice Site (SNP) | VAF 35/193 reads (18%) | catalogued as rs201946586; called by muse, mutect2, varscan2
- FAM149B1 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.02); catalogued as rs571636458, COSV54350162; called by muse, mutect2
- FAM153B | c.709G>T p.E237* (on ENST00000253490; = p.E160* on NM_001265615.1) | Nonsense Mutation (SNP) | VAF 50/544 reads (9%) | catalogued as COSV99498862; called by muse, mutect2
- FANCM | c.1778G>T p.R593L | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV57505503; called by muse, mutect2, varscan2
- FAT1 | c.1646G>T p.R549L | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV71673004; called by muse, mutect2, varscan2
- FGFR4 | c.1018G>A p.G340S | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472541408; called by muse, mutect2, varscan2
- FRAS1 | c.8323G>C p.D2775H | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV53588520; called by muse, mutect2, varscan2
- GDF3 | c.469G>T p.G157C | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61712234, COSV61713136; called by muse, mutect2, varscan2
- GRM5 | c.2342C>G p.T781S | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100553835; called by muse, mutect2, varscan2
- HDAC4 | c.2938G>T p.A980S | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV61874608; called by muse, mutect2, varscan2
- IGHV3-74 | c.21G>T p.W7C | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.246); catalogued as rs954243705; called by muse, mutect2, varscan2
- IL37 | c.51G>T p.W17C | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.253); catalogued as COSV99636397; called by muse, mutect2
- IMPG1 | c.1644G>T p.E548D | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.428); catalogued as COSV100886722; called by muse, mutect2, varscan2
- IQSEC1 | c.1487G>T p.R496L | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV99068600; called by muse, mutect2, varscan2
- KCNH5 | c.2755G>T p.E919* | Nonsense Mutation (SNP) | VAF 26/88 reads (30%) | catalogued as COSV59753880; called by muse, mutect2, varscan2
- KCNJ12 | c.26C>G p.P9R | Missense Mutation (SNP) | VAF 70/532 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781837859, COSV100055143; called by muse, mutect2, varscan2
- KCNK9 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs370302731; called by muse, mutect2
- KDM5C | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 113/228 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1556854381, COSV100855525; called by muse, mutect2, varscan2
- KDM7A | c.1933G>T p.V645L | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.234); catalogued as COSV50097954; called by muse, mutect2, varscan2
- KIAA1549L | c.2432C>A p.T811K (on ENST00000321505; = p.T1108K on NM_012194.3) | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs774799305, COSV99683151; called by muse, mutect2, varscan2
- KIF21B | c.2624G>T p.R875L | Missense Mutation (SNP) | VAF 37/478 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as rs371230464, COSV104407060; called by muse, mutect2
- KMT2C | c.5082+1G>T p.X1694_splice | Splice Site (SNP) | VAF 42/271 reads (15%) | catalogued as rs1476122660; called by muse, mutect2, varscan2
- KRTAP5-7 | c.475G>T p.V159L | Missense Mutation (SNP) | VAF 96/278 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV101273186; called by muse, varscan2
- LAMC2 | c.2579G>T p.G860V | Missense Mutation (SNP) | VAF 82/503 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.296); catalogued as rs768613031; called by muse, mutect2, varscan2
- LARP6 | c.1349C>A p.T450K | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100151056; called by muse, mutect2, varscan2
- LCT | c.4369C>T p.L1457F | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.431); catalogued as COSV99930668; called by muse, mutect2
- LNX2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs963005282, COSV60335104; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.377G>T p.S126I | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV58187557; called by muse, mutect2, varscan2
- MAGEH1 | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100746796, COSV61678734; called by muse, mutect2, varscan2
- METTL11B | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 53/315 reads (17%) | catalogued as COSV63029487; called by muse, mutect2, varscan2
- MGAT5B | c.1906G>A p.A636T (on ENST00000569840 / NM_001199172.2; = p.A634T on NM_144677.3) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1318500543, COSV56931218; called by muse, mutect2, varscan2
- MSH6 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 69/150 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as rs1342218617; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC16 | c.43282A>T p.R14428W | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66690355; called by muse, mutect2, varscan2
- MUC5B | c.13496C>G p.S4499C | Missense Mutation (SNP) | VAF 64/616 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV101500553, COSV71594333; called by muse, mutect2, varscan2
- MYO3A | c.4335dup p.L1446Ifs*3 | Frame Shift Ins (INS) | VAF 39/318 reads (12%) | catalogued as rs772558362; called by mutect2, pindel, varscan2
- MYO7B | c.4920C>A p.H1640Q | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV67352252; called by muse, mutect2, varscan2
- NEBL | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1040045632; called by muse, mutect2
- NFKBID | c.467C>T p.P156L (on ENST00000396901; = p.P308L on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs1440823199, COSV61727733; called by muse, mutect2, varscan2
- NLRP13 | c.148G>T p.G50W | Missense Mutation (SNP) | VAF 72/290 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs1310852384, COSV61622011, COSV61623829; called by muse, mutect2
- NLRP5 | c.2401C>A p.L801M | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs1280730149, COSV101173781; called by muse, mutect2, varscan2
- NOS1 | c.1906G>A p.V636M | Missense Mutation (SNP) | VAF 25/255 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV57610788; called by muse, mutect2
- NRF1 | c.574G>T p.G192* | Nonsense Mutation (SNP) | VAF 71/183 reads (39%) | catalogued as COSV99781685; called by muse, mutect2, varscan2
- NRG3 | c.1684C>T p.R562* (on ENST00000404547 / NM_001370084.1; = p.R538* on NM_001010848.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 32/123 reads (26%) | catalogued as rs766655914; called by muse, varscan2
- NRXN1 | c.253C>G p.R85G | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV68029352; called by muse, mutect2, varscan2
- OR11G2 | c.134G>T p.S45I | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.284); catalogued as COSV62131835; called by muse, mutect2, varscan2
- OR1A2 | c.448G>T p.V150L | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.136); catalogued as COSV67936258; called by muse, mutect2, varscan2
- OR2T12 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 44/452 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs200352170, COSV58776065, COSV58778849; called by muse, mutect2
- OR51S1 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as COSV59058120; called by muse, mutect2, varscan2
- OR51V1 | c.462G>T p.R154S | Missense Mutation (SNP) | VAF 65/322 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58314319; called by muse, mutect2, varscan2
- OR5AC2 | c.8T>C p.I3T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs1316183476; called by muse, mutect2, varscan2
- OSBPL7 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1285970123; called by muse, mutect2
- PCDH1 | c.1581G>T p.E527D | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV54621106; called by muse, mutect2, varscan2
- PCDH11X | c.3998G>A p.R1333K | Missense Mutation (SNP) | VAF 123/245 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV53496507; called by muse, mutect2, varscan2
- PCDHGA9 | c.2197G>T p.A733S | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); catalogued as rs1469979881; called by muse, mutect2, varscan2
- PDGFRA | c.3012G>C p.E1004D | Missense Mutation (SNP) | VAF 70/320 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV57269321; called by muse, varscan2
- PLCB1 | c.3394C>A p.R1132S | Missense Mutation (SNP) | VAF 157/381 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs755357721; called by muse, mutect2, varscan2
- PLCL2 | c.2944G>T p.E982* (on ENST00000615277 / NM_001144382.2; = p.E856* on NM_015184.5) | Nonsense Mutation (SNP) | VAF 72/280 reads (26%) | catalogued as COSV67621652; called by muse, mutect2, varscan2
- PLPPR4 | c.1120G>T p.G374C | Missense Mutation (SNP) | VAF 65/266 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV64565315; called by muse, mutect2, varscan2
- PLXNA4 | c.1096C>A p.R366S | Missense Mutation (SNP) | VAF 76/262 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV58127627; called by muse, mutect2, varscan2
- POLR3GL | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553763165; called by muse, mutect2, varscan2
- POM121L2 | c.1769C>T p.T590M | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs16897529; called by muse, mutect2, varscan2
- PPM1K | c.1047G>T p.W349C | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55798176; called by muse, mutect2, varscan2
- PRICKLE2 | c.1830C>G p.G610= (on ENST00000295902; = p.G554= on NM_198859.4) | Splice Region (SNP) | VAF 27/178 reads (15%) | catalogued as rs201427195; called by muse, mutect2, varscan2
- PRND | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 84/178 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV59896474, COSV59896881; called by muse, mutect2, varscan2
- PRSS38 | c.515C>A p.A172E | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV64542110; called by muse, mutect2
- PSMD13 | c.1018G>T p.V340L | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs761963967, COSV61501640; called by muse, mutect2, varscan2
- PYHIN1 | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 29/243 reads (12%) | PolyPhen probably damaging (0.934); catalogued as COSV63730723, COSV63732596; called by muse, mutect2, varscan2
- RAD51AP2 | c.1727T>C p.L576S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.389); catalogued as rs762303063; called by muse, mutect2, varscan2
- RIPOR1 | c.3599G>A p.R1200Q (on ENST00000379312 / NM_001193522.2; = p.R1196Q on NM_024519.4) | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99061988; called by muse, mutect2, varscan2
- RMND5A | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.329); catalogued as rs143570524, COSV52154678, COSV52155566; called by muse, mutect2, varscan2
- RPL10L | c.432C>A p.N144K | Missense Mutation (SNP) | VAF 67/302 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as rs1464110614, COSV53559837; called by muse, mutect2, varscan2
- RUNX1T1 | c.1297C>A p.L433I (on ENST00000265814 / NM_001198628.1; = p.L406I on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.368); catalogued as COSV56136755, COSV56140463, COSV56153085; called by muse, mutect2, varscan2
- RYR2 | c.12719C>T p.T4240M | Missense Mutation (SNP) | VAF 64/683 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV63714535; called by muse, mutect2
- SAA2 | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs373197707, COSV56776976; called by muse, mutect2, varscan2
- SERPINA6 | c.56C>A p.T19N | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV58586996; called by muse, mutect2, varscan2
- SLC2A6 | c.1339G>A p.V447I | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as rs781946360; called by muse, mutect2, varscan2
- SLC34A2 | c.1606T>A p.F536I | Missense Mutation (SNP) | VAF 69/437 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs1227346120, COSV65942763; called by muse, mutect2, varscan2
- SLC43A3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 24/99 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs1476621362, COSV61450317; called by muse, varscan2
- SLC6A13 | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 69/225 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs140692087; called by muse, mutect2, varscan2
- SLC6A7 | c.841C>A p.H281N | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs960870506, COSV57938755; called by muse, varscan2
- SLIT3 | c.2845G>T p.G949C | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100266752; called by muse, mutect2, varscan2
- SMARCAD1 | c.1693A>C p.N565H | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.106); catalogued as rs370363007; called by muse, mutect2, varscan2
- SPECC1L | c.190G>T p.G64* | Nonsense Mutation (SNP) | VAF 68/291 reads (23%) | catalogued as COSV58660795; called by muse, mutect2, varscan2
- SPINK6 | c.230C>G p.P77R | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV57778946; called by muse, mutect2
- SPOCD1 | c.2869G>T p.G957W | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99930446; called by muse, mutect2, varscan2
- SPSB4 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV100141745; called by muse, mutect2, varscan2
- SPTA1 | c.6126G>T p.E2042D | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.088); catalogued as COSV63751279, COSV63761204; called by muse, mutect2, varscan2
- ST6GAL1 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 34/286 reads (12%) | PolyPhen possibly damaging (0.874); catalogued as rs1450021505; called by muse, mutect2, varscan2
- STX4 | c.535A>C p.S179R | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs1230184420; called by muse, mutect2
- TBC1D3B | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 79/606 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs768433492; called by muse, mutect2, varscan2
- TBK1 | c.2155A>G p.M719V | Missense Mutation (SNP) | VAF 39/308 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770780416; called by muse, varscan2
- TCTEX1D2 | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV57487827, COSV57489367; called by muse, mutect2, varscan2
- TG | c.4667C>T p.T1556I | Missense Mutation (SNP) | VAF 230/340 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as rs1479288358; called by muse, mutect2, varscan2
- TLE1 | c.1219G>C p.A407P | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs751293312; called by muse, mutect2, varscan2
- TNFRSF21 | c.1148A>G p.Q383R | Missense Mutation (SNP) | VAF 39/301 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs367859062; called by muse, mutect2, varscan2
- TRAIP | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs368177362, COSV58913292; called by mutect2, varscan2
- TRAV8-7 | c.122A>G p.N41S | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.172); catalogued as rs1158459986; called by muse, mutect2, varscan2
- TRPM5 | c.403G>T p.V135F | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1353257964; called by muse, mutect2, varscan2
- UNC79 | c.6808C>G p.L2270V (on ENST00000393151 / NM_001346218.2; = p.L2093V on NM_020818.5) | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.797); catalogued as COSV56417377; called by muse, mutect2, varscan2
- URB1 | c.5098G>T p.A1700S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.741); catalogued as rs144291646; called by muse, mutect2, varscan2
- VCX3A | c.314G>T p.S105I | Missense Mutation (SNP) | VAF 68/337 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs375880156; called by muse, varscan2
- ZADH2 | c.769G>T p.V257L | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0.019); catalogued as rs768529601; called by muse, mutect2, varscan2
- ZC3H6 | c.2345C>T p.A782V | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs769924975, COSV59668909; called by muse, mutect2, varscan2
- ZFHX4 | c.6170C>T p.P2057L | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.038); catalogued as COSV50668053, COSV51475464; called by muse, varscan2
- ZIK1 | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 22/211 reads (10%) | catalogued as COSV56737446; called by muse, mutect2, varscan2
- ZNF22 | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as COSV53584526; called by mutect2, varscan2
- ZNF415 | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as rs1213586457, COSV54699275; called by muse, mutect2, varscan2
- ZNF418 | c.491G>T p.S164I | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.737); catalogued as COSV99061542; called by muse, mutect2, varscan2
- ZNF528 | c.980G>T p.C327F | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV100846748; called by muse, mutect2
- ZNF585B | c.658G>T p.G220W | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100459641; called by muse, mutect2, varscan2
- ZNF626 | c.769T>A p.Y257N | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV74129593; called by muse, mutect2, varscan2
- ZNF880 | c.1684A>T p.N562Y | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV69906285; called by muse, mutect2
- ABCB7 | c.1451del p.G484Afs*21 (on ENST00000373394 / NM_001271696.3; = p.G485Afs*21 on NM_004299.6) | Frame Shift Del (DEL) | VAF 42/224 reads (19%) | called by mutect2, pindel, varscan2
- ABCC11 | c.3304G>C p.E1102Q | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ACACB | c.2261G>T p.G754V | Missense Mutation (SNP) | VAF 100/306 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ACLY | c.2938-2A>G p.X980_splice | Splice Site (SNP) | VAF 29/120 reads (24%) | called by muse, mutect2, varscan2
- ACTN3 | c.1349G>T p.R450L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ADCY2 | c.1294C>G p.L432V | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ADGRG4 | c.1464G>T p.Q488H | Missense Mutation (SNP) | VAF 85/136 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- ADGRG4 | c.1644G>T p.M548I | Missense Mutation (SNP) | VAF 81/147 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADRA1A | c.288G>T p.R96S | Missense Mutation (SNP) | VAF 151/421 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- AGAP2 | c.404del p.G135Afs*59 | Frame Shift Del (DEL) | VAF 21/112 reads (19%) | called by mutect2, pindel
- AGO3 | c.2435T>G p.F812C | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- AGPAT3 | c.424G>C p.V142L | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- AGXT | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 82/321 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- ANK2 | c.10016C>A p.A3339E | Missense Mutation (SNP) | VAF 45/254 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD24 | c.1249G>T p.G417C | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD30A | c.2129T>A p.I710K (on ENST00000611781; = p.I654K on NM_052997.2) | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated (0.94); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ANKRD34C | c.145A>T p.M49L | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKS1B | c.3247G>T p.D1083Y (on ENST00000547776 / NM_152788.4; = p.D249Y on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANO5 | c.1010G>T p.S337I | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- APBA1 | c.999G>T p.E333D | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ARAP1 | c.835G>T p.G279W (on ENST00000393609 / NM_001040118.2; = p.G34W on NM_015242.4) | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ARC | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ARHGEF11 | c.3518G>T p.G1173V | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ASTN1 | c.1079C>A p.T360N | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); called by muse, mutect2
- ATG9B | c.558G>T p.W186C | Missense Mutation (SNP) | VAF 69/268 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATM | c.8584+1G>T p.X2862_splice | Splice Site (SNP) | VAF 88/335 reads (26%) | called by muse, mutect2, varscan2
- ATP2B4 | c.1982A>T p.E661V | Missense Mutation (SNP) | VAF 72/375 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- ATP6V1E1 | c.213G>T p.Q71H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- AXIN1 | c.1771G>T p.G591C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- AXL | c.533_534insTTT p.V178_P179insF | In Frame Ins (INS) | VAF 36/128 reads (28%) | called by pindel, varscan2
- BCAN | c.2210-3T>G | Splice Region (SNP) | VAF 18/177 reads (10%) | called by muse, mutect2, varscan2
- BHLHE40 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 34/245 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- C12orf66 | c.8A>T p.E3V | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); called by muse, varscan2
- C1QC | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- C9orf131 | c.1183C>A p.L395M | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CACNA1B | c.6016G>T p.A2006S | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CACNA1E | c.5700G>T p.Q1900H | Missense Mutation (SNP) | VAF 54/333 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- CACNA1I | c.519C>A p.N173K | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CAMSAP3 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CCDC141 | c.3799C>A p.P1267T | Missense Mutation (SNP) | VAF 66/372 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- CCDC185 | c.1844G>T p.R615L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.063); called by muse, varscan2
- CCM2 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 47/438 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCNB2 | c.398A>T p.D133V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CD28 | c.653A>T p.Y218F | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CD300LD | c.41-1G>T p.X14_splice | Splice Site (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- CDC14C | c.1649C>T p.P550L (on ENST00000428251; = p.P443L on NM_152627.3) | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- CELF2 | c.1072G>C p.A358P (on ENST00000416382 / NM_001025077.3; = p.A365P on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/344 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- CENPE | c.5515G>A p.V1839I | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2
- CENPU | c.26C>A p.P9Q | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.024); called by mutect2, varscan2
- CFAP100 | c.313C>A p.Q105K | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.039); called by muse, mutect2
- CFH | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 72/435 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CHRM3 | c.1165C>A p.L389M | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CLCNKA | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC14A | c.416C>A p.T139N | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- CLEC4E | c.275A>T p.Y92F | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COG8 | c.1645C>T p.Q549* | Nonsense Mutation (SNP) | VAF 75/340 reads (22%) | called by muse, mutect2, varscan2
- COL11A1 | c.3372A>T p.E1124D | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CPN1 | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 98/338 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- CRB1 | c.3569A>T p.N1190I | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRYBB2 | c.590_600del p.Q197Lfs*35 | Frame Shift Del (DEL) | VAF 35/142 reads (25%) | called by mutect2, pindel, varscan2
- CSMD3 | c.3135A>T p.E1045D (on ENST00000297405 / NM_001363185.1; = p.E941D on NM_052900.3) | Missense Mutation (SNP) | VAF 177/553 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- CTIF | c.1391A>G p.E464G | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); called by muse, mutect2
- CYP11A1 | c.1458A>T p.E486D | Missense Mutation (SNP) | VAF 44/338 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- CYP2C18 | c.1468G>C p.V490L | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCDC1 | c.2164del p.I722Lfs*15 | Frame Shift Del (DEL) | VAF 43/188 reads (23%) | called by mutect2, pindel, varscan2
- DDX24 | c.1096A>G p.T366A | Missense Mutation (SNP) | VAF 57/273 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DGKD | c.2326A>T p.I776L (on ENST00000264057 / NM_152879.3; = p.I732L on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DISC1 | c.68G>C p.G23A | Missense Mutation (SNP) | VAF 75/529 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- DLGAP4 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- DNAL4 | c.11C>A p.T4K | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.92); PolyPhen benign (0.007); called by muse, mutect2
- DOCK3 | c.2550A>G p.E850= | Splice Region (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- DOK3 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- DPYD | c.2443-1G>A p.X815_splice | Splice Site (SNP) | VAF 33/314 reads (11%) | called by muse, mutect2, varscan2
- DUOXA1 | c.874A>T p.M292L | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- EBF3 | c.64A>T p.S22C | Missense Mutation (SNP) | VAF 49/267 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- ECEL1 | c.1850G>A p.G617D | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFHC2 | c.292A>T p.R98* | Nonsense Mutation (SNP) | VAF 31/164 reads (19%) | called by muse, mutect2, varscan2
- EHHADH | c.1841T>A p.I614N | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ELAPOR2 | c.1180del p.D394Ifs*57 (on ENST00000450689 / NM_001142749.3; = p.D227Ifs*57 on NM_152748.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 26/141 reads (18%) | called by mutect2, pindel, varscan2
- ELP2 | c.613G>T p.G205* | Nonsense Mutation (SNP) | VAF 64/337 reads (19%) | called by muse, mutect2, varscan2
- EML1 | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- EML2 | c.158T>A p.L53Q | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPM2A | c.543del p.E182Kfs*8 | Frame Shift Del (DEL) | VAF 18/194 reads (9%) | called by mutect2, pindel
- ESRRG | c.171C>A p.S57R | Missense Mutation (SNP) | VAF 36/265 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- FAM135B | c.1143C>A p.N381K | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- FAM153B | c.710A>T p.E237V (on ENST00000253490; = p.E160V on NM_001265615.1) | Missense Mutation (SNP) | VAF 50/546 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.088); called by muse, mutect2
- FAM170B | c.510G>T p.K170N | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM71E2 | c.1967C>A p.P656Q | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FANCB | c.512A>T p.Q171L | Missense Mutation (SNP) | VAF 71/114 reads (62%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FARP1 | c.2591C>G p.P864R | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- FBN2 | c.3149C>A p.T1050K | Missense Mutation (SNP) | VAF 110/438 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- FBN3 | c.4225G>T p.A1409S | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FGD5 | c.3242C>A p.A1081D | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- FMN2 | c.95T>A p.V32E | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FUBP3 | c.1239G>C p.Q413H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GABPA | c.1060G>C p.E354Q | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- GABRA1 | c.605C>A p.P202Q | Missense Mutation (SNP) | VAF 38/336 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- GABRD | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GALNT9 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 78/241 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GANC | c.585G>A p.W195* | Nonsense Mutation (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2, varscan2
- GID4 | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GIMD1 | c.161A>T p.H54L | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPR148 | c.539C>A p.P180H | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GPR65 | c.382A>T p.R128* | Nonsense Mutation (SNP) | VAF 57/272 reads (21%) | called by muse, mutect2, varscan2
- GXYLT2 | c.1090G>T p.G364C | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- HERC5 | c.2242C>A p.P748T | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- HERC5 | c.2243C>A p.P748H | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- HIPK4 | c.467T>A p.V156E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HNRNPU | c.1500+1G>A p.X500_splice (on ENST00000283179; = p.X562_splice on NM_004501.3) | Splice Site (SNP) | VAF 14/137 reads (10%) | called by muse, mutect2, varscan2
- HRNR | c.7361C>A p.S2454Y | Missense Mutation (SNP) | VAF 209/1331 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- HSPB6 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- HTR4 | c.1000T>C p.Y334H | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- ICE1 | c.3759G>T p.Q1253H | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- IFNL1 | c.568T>A p.C190S | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- IL20RB | c.492G>T p.E164D | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- IL37 | c.50G>T p.W17L | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- INSC | c.1642C>A p.P548T | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- IQGAP2 | c.568G>C p.G190R | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IRX5 | c.511_513dup p.L171dup | In Frame Ins (INS) | VAF 30/338 reads (9%) | called by mutect2, pindel
- JARID2 | c.182-2A>G p.X61_splice | Splice Site (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2
- KCNH5 | c.1321A>G p.T441A | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KCNQ2 | c.1221G>T p.K407N (on ENST00000359125 / NM_172107.4; = p.K397N on NM_004518.6) | Missense Mutation (SNP) | VAF 185/409 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- KHDRBS2 | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- KHDRBS3 | c.296G>C p.G99A | Missense Mutation (SNP) | VAF 160/246 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF27 | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF2B | c.1787A>T p.E596V | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KIF7 | c.2827C>A p.L943M | Missense Mutation (SNP) | VAF 98/357 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- LATS2 | c.1865A>C p.N622T | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2
- LILRA5 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 100/489 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- LMO2 | c.283G>T p.A95S (on ENST00000395833 / NM_001142315.2; = p.A164S on NM_005574.4) | Missense Mutation (SNP) | VAF 50/242 reads (21%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LPCAT2 | c.537A>T p.L179F | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); called by muse, mutect2
- LPCAT2 | c.539G>C p.R180P | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); called by muse, mutect2
- LRIT2 | c.356C>A p.P119Q | Missense Mutation (SNP) | VAF 71/293 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRP1 | c.12144A>T p.T4048= | Splice Region (SNP) | VAF 17/96 reads (18%) | called by muse, mutect2, varscan2
- LRP1B | c.1849A>T p.N617Y | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LRRC37A3 | c.2290G>T p.G764* | Nonsense Mutation (SNP) | VAF 105/562 reads (19%) | called by muse, mutect2, varscan2
- LSS | c.872G>T p.W291L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LVRN | c.1307T>A p.L436H | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- LY86 | c.143T>A p.L48* | Nonsense Mutation (SNP) | VAF 44/157 reads (28%) | called by muse, mutect2, varscan2
- MAP1B | c.2602A>T p.K868* | Nonsense Mutation (SNP) | VAF 78/256 reads (30%) | called by muse, mutect2, varscan2
- MCUR1 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- METTL15 | c.1022G>T p.R341I | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.124); called by muse, mutect2
- MOAP1 | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- MORC1 | c.1027C>A p.Q343K | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MRGPRF | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC2 | c.2801G>T p.S934I | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0.02); called by muse, mutect2, varscan2
- MUC5AC | c.706G>T p.G236W | Missense Mutation (SNP) | VAF 83/248 reads (33%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MUC5B | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC7 | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- MYCT1 | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); called by muse, mutect2
- MYH8 | c.3177G>T p.E1059D | Missense Mutation (SNP) | VAF 78/317 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- MYO18B | c.4765T>A p.C1589S | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO5A | c.1969T>G p.Y657D | Missense Mutation (SNP) | VAF 19/350 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- NDN | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2
- NDRG1 | c.192C>A p.D64E | Missense Mutation (SNP) | VAF 74/1108 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- NHLRC3 | c.921A>T p.Q307H | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- NLRP10 | c.1733G>C p.G578A | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- NLRP14 | c.2250_2251del p.C750* | Frame Shift Del (DEL) | VAF 106/368 reads (29%) | called by pindel, varscan2
- NOS1 | c.2123C>A p.S708Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.934); called by muse, mutect2
- NOTCH3 | c.4381G>T p.G1461C | Missense Mutation (SNP) | VAF 60/315 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- NOTCH4 | c.1445A>T p.Q482L | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- NPC1 | c.376A>T p.T126S | Missense Mutation (SNP) | VAF 70/345 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPIPB4 | c.1079C>A p.P360H | Missense Mutation (SNP) | VAF 39/408 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); called by muse, varscan2
- NPTX2 | c.598A>T p.S200C | Missense Mutation (SNP) | VAF 52/260 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- NRK | c.4393C>T p.P1465S | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NT5C1B | c.676C>G p.Q226E (on ENST00000359846 / NM_001199086.2; = p.Q166E on NM_033253.4) | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP62CL | c.356T>A p.L119* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- NWD1 | c.2373_2391del p.Q792Wfs*87 | Frame Shift Del (DEL) | VAF 36/220 reads (16%) | called by mutect2, pindel
- NXPH2 | c.284C>A p.A95E | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- OR14I1 | c.362A>T p.Y121F | Missense Mutation (SNP) | VAF 98/284 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- OR2AG1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- OR2T10 | c.305A>T p.Y102F | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4C12 | c.300T>G p.Y100* | Nonsense Mutation (SNP) | VAF 47/236 reads (20%) | called by muse, mutect2, varscan2
- OR4C6 | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.139); called by muse, varscan2
- OR51V1 | c.461G>C p.R154T | Missense Mutation (SNP) | VAF 62/323 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR52J3 | c.359T>C p.M120T | Missense Mutation (SNP) | VAF 70/193 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- OR56A5 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8G1 | c.670A>T p.S224C | Missense Mutation (SNP) | VAF 100/306 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- OSR2 | c.901C>G p.R301G (on ENST00000297565 / NM_001142462.3; = p.G273= on NM_053001.3) | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- OSR2 | c.902G>T p.R301L (on ENST00000297565 / NM_001142462.3; = p.G274C on NM_053001.3) | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- PCDHB10 | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 41/290 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHB9 | c.1486C>A p.P496T | Missense Mutation (SNP) | VAF 113/546 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PCDHB9 | c.1487C>A p.P496Q | Missense Mutation (SNP) | VAF 111/547 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PCDHGA12 | c.1606del p.D536Tfs*13 | Frame Shift Del (DEL) | VAF 55/253 reads (22%) | called by mutect2, pindel, varscan2
- PCDHGA4 | c.2034G>T p.Q678H | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCDHGB3 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCNX1 | c.4635A>T p.P1545= | Splice Region (SNP) | VAF 29/129 reads (22%) | called by muse, mutect2, varscan2
- PDE1A | c.1246T>C p.S416P | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE4A | c.621-1G>T p.X207_splice | Splice Site (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- PDE4DIP | c.2785_2786del p.N929Qfs*16 | Frame Shift Del (DEL) | VAF 42/388 reads (11%) | called by mutect2, pindel
- PDZRN3 | c.1432G>T p.V478L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.18); called by mutect2, varscan2
- PEAK1 | c.5144G>T p.G1715V | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.058); called by mutect2, varscan2
- PER1 | c.3448A>T p.R1150W | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHF2 | c.3101G>T p.G1034V | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PHF21A | c.23A>T p.E8V | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PIEZO2 | c.6070C>A p.L2024M | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- PKN2 | c.662A>T p.E221V | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- PLD5 | c.1276A>G p.T426A (on ENST00000442594; = p.T364A on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/264 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.01); called by muse, mutect2
- PLEKHD1 | c.1013A>T p.Q338L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PLK1 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- PMFBP1 | c.801C>G p.N267K | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- PMS2 | c.1681A>C p.K561Q | Missense Mutation (SNP) | VAF 34/345 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PNPLA7 | c.1818G>T p.Q606H | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- POLR3F | c.368T>C p.I123T | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- POPDC2 | c.910C>G p.L304V | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- POTEI | c.860T>C p.V287A | Missense Mutation (SNP) | VAF 38/531 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.218); called by muse, mutect2
- POTEJ | c.1627A>T p.S543C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.147); called by mutect2, varscan2
- POTEJ | c.1628G>T p.S543I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.049); called by mutect2, varscan2
- POU5F1B | c.514G>T p.G172W | Missense Mutation (SNP) | VAF 96/806 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R2B | c.400C>G p.R134G | Missense Mutation (SNP) | VAF 92/391 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, varscan2
- PRKAR1B | c.791G>T p.R264L | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRR14 | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- PSAP | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 22/355 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PSMD8 | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTK2 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 37/430 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PTPRB | c.4417G>C p.V1473L | Missense Mutation (SNP) | VAF 74/327 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PXDN | c.4134T>A p.D1378E | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RABGGTA | c.1240G>T p.V414L | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RBFOX1 | c.961C>G p.P321A | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- REC114 | c.27G>C p.L9F | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.189); called by mutect2, varscan2
- RFX7 | c.3900G>C p.L1300F (on ENST00000559447 / NM_001368074.1; = p.L1397F on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RIMS2 | c.1236G>T p.M412I (on ENST00000666250 / NM_001348490.2; = p.M220I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 147/298 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- RPA1 | c.1306G>C p.G436R | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- RTP1 | c.710G>T p.C237F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0); called by mutect2, varscan2
- RXFP3 | c.182del p.P61Rfs*45 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel, varscan2
- SALL1 | c.1114T>A p.S372T | Missense Mutation (SNP) | VAF 58/293 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SASH3 | c.917T>A p.L306Q | Missense Mutation (SNP) | VAF 73/130 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SBK3 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- SBNO1 | c.3422G>T p.R1141I (on ENST00000420886; = p.R1140I on NM_018183.5) | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SCARF1 | c.2316A>C p.R772S | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SDK2 | c.5276T>G p.L1759R | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- SEMA4C | c.1823G>T p.R608L | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SEMA4D | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 34/159 reads (21%) | called by muse, mutect2, varscan2
- SH3GL2 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- SIAH3 | c.714C>A p.N238K | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- SKI | c.1015A>G p.T339A | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC16A9 | c.412C>G p.L138V | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, varscan2
- SLC17A8 | c.1442A>T p.Q481L | Missense Mutation (SNP) | VAF 78/268 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- SLC35F3 | c.688C>A p.H230N (on ENST00000366617 / NM_001300845.1; = p.H299N on NM_173508.4) | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- SLC6A5 | c.1625G>T p.G542V | Missense Mutation (SNP) | VAF 168/493 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- SLC8A1 | c.1721A>G p.Y574C | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC9A3R1 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMARCC1 | c.2479G>T p.D827Y | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- SNTG2 | c.830G>T p.R277M | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- SNTG2 | c.1568C>G p.P523R | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SON | c.1684G>T p.G562W | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SORBS1 | c.2864A>T p.Q955L (on ENST00000361941 / NM_001034954.2; = p.Q605L on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SPAG17 | c.4879C>A p.L1627I | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- SPTB | c.4812G>C p.E1604D | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- SPTB | c.3118G>T p.E1040* | Nonsense Mutation (SNP) | VAF 75/339 reads (22%) | called by muse, mutect2, varscan2
- SSC5D | c.1829C>G p.A610G | Missense Mutation (SNP) | VAF 65/408 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STK11 | c.988_989insT p.D330Vfs*30 | Frame Shift Ins (INS) | VAF 55/116 reads (47%) | called by mutect2, pindel, varscan2
- TAF4B | c.325A>T p.N109Y | Missense Mutation (SNP) | VAF 77/322 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- TAS1R1 | c.916T>C p.S306P | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TCAF2 | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by mutect2, varscan2
- TECPR2 | c.3103G>C p.D1035H | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENT4A | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 41/236 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- TEX47 | c.694A>T p.M232L | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- THOC2 | c.1527G>T p.W509C | Missense Mutation (SNP) | VAF 49/78 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THSD4 | c.1554C>A p.N518K | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- TIMM44 | c.987+8C>A | Splice Region (SNP) | VAF 12/212 reads (6%) | called by muse, mutect2
- TLCD1 | c.641T>G p.L214R | Missense Mutation (SNP) | VAF 83/482 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TLE3 | c.125+1G>A p.X42_splice | Splice Site (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- TMEM185A | c.805C>A p.H269N | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.07); called by muse, varscan2
- TMEM260 | c.1950G>T p.M650I | Missense Mutation (SNP) | VAF 79/349 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TNKS2 | c.1603G>T p.G535W | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TPO | c.638T>C p.I213T | Missense Mutation (SNP) | VAF 15/530 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- TRAPPC6B | c.383G>C p.G128A (on ENST00000330149 / NM_001079537.2; = p.G100A on NM_177452.4) | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRMT6 | c.1215+1G>A p.X405_splice | Splice Site (SNP) | VAF 60/189 reads (32%) | called by muse, mutect2, varscan2
- TRPC7 | c.1715T>A p.L572Q | Missense Mutation (SNP) | VAF 65/268 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSC2 | c.3367G>A p.G1123R | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TSC2 | c.4407del p.R1470Afs*6 | Frame Shift Del (DEL) | VAF 32/134 reads (24%) | called by mutect2, pindel*, varscan2
- TTC21A | c.2488A>T p.I830F | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTC21B | c.139A>G p.T47A | Missense Mutation (SNP) | VAF 38/423 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2
- TXNRD1 | c.1236del p.T413Hfs*7 (on ENST00000525566 / NM_001093771.3; = p.T315Hfs*7 on NM_003330.4) | Frame Shift Del (DEL) | VAF 68/258 reads (26%) | called by mutect2, pindel, varscan2
- UGGT2 | c.3741-3C>T | Splice Region (SNP) | VAF 32/103 reads (31%) | called by muse, mutect2, varscan2
- URB1 | c.547G>T p.V183L | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- USP24 | c.861+1del p.X287_splice | Splice Site (DEL) | VAF 36/167 reads (22%) | called by mutect2, pindel, varscan2
- USP32 | c.4387G>T p.D1463Y | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- USP34 | c.2917_2918del p.Q973Kfs*8 | Frame Shift Del (DEL) | VAF 36/229 reads (16%) | called by mutect2, pindel, varscan2
- USP50 | c.200_201insT p.L68Afs*17 (on ENST00000616326; = p.L68Afs*20 on NM_203494.5) | Frame Shift Ins (INS) | VAF 22/189 reads (12%) | called by mutect2, pindel, varscan2
- USP9X | c.28G>T p.V10F | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- UVRAG | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); called by muse, mutect2
- UVRAG | c.1418G>T p.S473I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, varscan2
- VCX3B | c.314G>T p.S105I | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.137); called by mutect2, varscan2
- VGLL2 | c.308T>C p.F103S | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- VIPR2 | c.301A>T p.T101S | Missense Mutation (SNP) | VAF 44/247 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- WDR83 | c.784T>A p.W262R | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WHAMM | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- WRNIP1 | c.1815G>T p.R605S | Missense Mutation (SNP) | VAF 102/378 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ZFAND4 | c.2041G>C p.E681Q | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- ZFHX4 | c.2812G>A p.V938I | Missense Mutation (SNP) | VAF 78/379 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZFP90 | c.876G>T p.R292S | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- ZFPM2 | c.35T>A p.I12N | Missense Mutation (SNP) | VAF 15/233 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); called by muse, mutect2
- ZKSCAN2 | c.1055T>A p.L352Q | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF214 | c.786G>T p.L262F | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF264 | c.160+1G>T p.X54_splice | Splice Site (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- ZNF587B | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 23/177 reads (13%) | called by muse, mutect2
- ZNF667 | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- ZNF728 | c.768C>A p.Y256* | Nonsense Mutation (SNP) | VAF 44/392 reads (11%) | called by muse, mutect2, varscan2
- ZNF804B | c.3103A>G p.T1035A | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF808 | c.595A>T p.R199W | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ZNF83 | c.1327T>G p.S443A | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.458); called by muse, mutect2
- ZNF91 | c.78G>T p.E26D | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- AASDH | c.465A>T p.L155= | Silent (SNP) | VAF 31/281 reads (11%) | called by muse, mutect2, varscan2
- ABCA12 | c.4251G>T p.R1417= (on ENST00000272895 / NM_173076.3; = p.R1099= on NM_015657.3) | Silent (SNP) | VAF 80/386 reads (21%) | called by muse, mutect2, varscan2
- ABI3BP | c.2889G>A p.R963= | Silent (SNP) | VAF 8/172 reads (5%) | catalogued as COSV52534227; called by muse, mutect2
- ACIN1 | c.4005G>T p.R1335= | Silent (SNP) | VAF 28/106 reads (26%) | called by muse, mutect2, varscan2
- ACSM2A | c.204C>A p.A68= | Silent (SNP) | VAF 34/177 reads (19%) | called by muse, mutect2
- ACTN3 | c.1350C>A p.R450= | Silent (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- ADAMTSL2 | c.43C>T p.L15= | Silent (SNP) | VAF 42/206 reads (20%) | called by muse, mutect2, varscan2
- ADGRG4 | c.7176C>A p.A2392= | Silent (SNP) | VAF 42/74 reads (57%) | called by muse, mutect2, varscan2
- ANO5 | c.2181A>T p.I727= | Silent (SNP) | VAF 80/321 reads (25%) | catalogued as COSV100202368; called by muse, varscan2
- APOB | c.12030C>A p.G4010= | Silent (SNP) | VAF 67/365 reads (18%) | called by muse, mutect2, varscan2
- ATP8B3 | c.2091G>C p.L697= | Silent (SNP) | VAF 54/166 reads (33%) | called by muse, mutect2, varscan2
- ATXN1L | c.1608C>T p.S536= | Silent (SNP) | VAF 50/274 reads (18%) | called by muse, mutect2, varscan2
- B3GAT1 | c.13C>A p.R5= | Silent (SNP) | VAF 45/236 reads (19%) | catalogued as COSV56995458; called by muse, mutect2, varscan2
- BIN1 | c.1308C>T p.S436= | Silent (SNP) | VAF 21/180 reads (12%) | catalogued as rs760959487; called by muse, mutect2, varscan2
- BMP7 | c.1191G>C p.A397= | Silent (SNP) | VAF 113/575 reads (20%) | called by muse, mutect2, varscan2
- C14orf180 | c.390G>T p.T130= | Silent (SNP) | VAF 32/134 reads (24%) | called by muse, mutect2, varscan2
- C18orf54 | c.657A>G p.P219= | Silent (SNP) | VAF 61/243 reads (25%) | called by muse, mutect2, varscan2
- C2CD4D | c.951C>T p.R317= | Silent (SNP) | VAF 84/253 reads (33%) | called by muse, mutect2, varscan2
- CACNA1G | c.4660C>A p.R1554= | Silent (SNP) | VAF 74/220 reads (34%) | called by muse, mutect2, varscan2
- CAMK2B | c.1299C>A p.P433= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99322864; called by muse, mutect2, varscan2
- CAMSAP3 | c.102G>A p.A34= | Silent (SNP) | VAF 19/105 reads (18%) | called by muse, mutect2, varscan2
- CFAP46 | c.7125C>A p.G2375= | Silent (SNP) | VAF 30/147 reads (20%) | catalogued as COSV54148302; called by muse, mutect2, varscan2
- CGN | c.2169G>C p.T723= | Silent (SNP) | VAF 33/196 reads (17%) | called by muse, mutect2, varscan2
- CHST1 | c.750G>A p.T250= | Silent (SNP) | VAF 38/238 reads (16%) | catalogued as rs776340776, COSV57323205; called by muse, mutect2, varscan2
- COL18A1 | c.1821A>T p.S607= (on ENST00000359759 / NM_130444.3; = p.S372= on NM_030582.4) | Silent (SNP) | VAF 31/133 reads (23%) | called by muse, mutect2, varscan2
- CSMD1 | c.3426C>T p.G1142= (on ENST00000520002; = p.G1141= on NM_033225.6) | Silent (SNP) | VAF 22/238 reads (9%) | catalogued as rs368141855; called by muse, mutect2
- DIDO1 | c.477G>T p.L159= | Silent (SNP) | VAF 123/552 reads (22%) | called by muse, mutect2, varscan2
- DKC1 | c.342G>T p.R114= | Silent (SNP) | VAF 66/117 reads (56%) | called by muse, mutect2, varscan2
- DLGAP2 | c.861C>A p.G287= | Silent (SNP) | VAF 90/221 reads (41%) | called by muse, mutect2, varscan2
- DSG1 | c.735G>T p.G245= | Silent (SNP) | VAF 92/380 reads (24%) | catalogued as rs1449413200, COSV57138921; called by mutect2, varscan2
- EFCAB6 | c.3318G>A p.T1106= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as rs139389166; called by muse, mutect2, varscan2
- EPHA6 | c.783C>A p.L261= | Silent (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- EYA4 | c.639C>A p.S213= | Silent (SNP) | VAF 32/241 reads (13%) | catalogued as COSV62045652; called by muse, mutect2, varscan2
- EYS | c.4438A>C p.R1480= | Silent (SNP) | VAF 93/299 reads (31%) | called by muse, mutect2, varscan2
- FAM83B | c.1347G>T p.A449= | Silent (SNP) | VAF 62/255 reads (24%) | catalogued as rs141100648; called by muse, mutect2, varscan2
- FAM83H | c.621C>T p.R207= | Silent (SNP) | VAF 15/496 reads (3%) | catalogued as rs376361154; called by muse, mutect2
- FAT4 | c.13461G>T p.A4487= | Silent (SNP) | VAF 46/215 reads (21%) | catalogued as COSV58671097; called by muse, mutect2, varscan2
- FCHSD1 | c.1732C>A p.R578= | Silent (SNP) | VAF 81/345 reads (23%) | called by muse, mutect2, varscan2
- FCRLA | c.1002G>T p.G334= (on ENST00000367959; = p.G311= on NM_032738.4) | Silent (SNP) | VAF 34/474 reads (7%) | called by muse, mutect2
- FN3KRP | c.15G>T p.L5= | Silent (SNP) | VAF 24/118 reads (20%) | called by muse, varscan2
- FYB1 | c.258T>A p.T86= | Silent (SNP) | VAF 85/389 reads (22%) | called by muse, mutect2, varscan2
- GBE1 | c.1083C>T p.S361= | Silent (SNP) | VAF 16/147 reads (11%) | catalogued as rs377496485; called by muse, mutect2, varscan2
- GCNT1 | c.576G>T p.R192= | Silent (SNP) | VAF 30/141 reads (21%) | called by muse, mutect2, varscan2
- GPR63 | c.1182G>C p.P394= | Silent (SNP) | VAF 31/217 reads (14%) | called by muse, mutect2, varscan2
- GRIP2 | c.1074C>A p.I358= (on ENST00000619221; = p.I261= on NM_001080423.4) | Silent (SNP) | VAF 26/252 reads (10%) | called by muse, mutect2, varscan2
- H2BC3 | c.372C>T p.S124= | Silent (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- HDAC9 | c.2625A>T p.T875= | Silent (SNP) | VAF 9/152 reads (6%) | catalogued as rs1220151549; called by muse, mutect2
- HHLA2 | c.1020A>T p.T340= | Silent (SNP) | VAF 34/135 reads (25%) | called by muse, mutect2, varscan2
- HNF4A | c.1248G>A p.Q416= | Silent (SNP) | VAF 264/531 reads (50%) | called by muse, mutect2, varscan2
- HRNR | c.1242C>A p.G414= | Silent (SNP) | VAF 78/468 reads (17%) | called by muse, mutect2, varscan2
- INTS7 | c.2826A>G p.Q942= | Silent (SNP) | VAF 45/286 reads (16%) | catalogued as rs772149595; called by muse, mutect2, varscan2
- IQGAP2 | c.3934C>A p.R1312= | Silent (SNP) | VAF 34/188 reads (18%) | catalogued as COSV99167063; called by muse, mutect2, varscan2
- KIAA0100 | c.2088G>A p.V696= | Silent (SNP) | VAF 42/392 reads (11%) | called by muse, mutect2, varscan2
- KISS1R | c.444G>A p.L148= | Silent (SNP) | VAF 41/396 reads (10%) | called by muse, mutect2, varscan2
- KRTAP10-1 | c.621C>A p.S207= | Silent (SNP) | VAF 65/468 reads (14%) | called by muse, mutect2, varscan2
- LHX2 | c.582G>T p.A194= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as COSV65318897; called by muse, mutect2
- LRP1 | c.9348G>A p.L3116= | Silent (SNP) | VAF 66/207 reads (32%) | catalogued as COSV54511676, COSV54529745; called by muse, mutect2, varscan2
- LRP4 | c.321C>G p.P107= | Silent (SNP) | VAF 84/312 reads (27%) | called by muse, mutect2, varscan2
- LYPD6B | c.315C>A p.I105= (on ENST00000409029 / NM_001317004.1; = p.I129= on NM_177964.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/208 reads (17%) | called by muse, varscan2
- MAGEE1 | c.342C>G p.T114= | Silent (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2, varscan2
- MASP1 | c.621C>A p.P207= | Silent (SNP) | VAF 30/262 reads (11%) | called by muse, mutect2, varscan2
- MCF2L2 | c.2092C>T p.L698= | Silent (SNP) | VAF 26/174 reads (15%) | called by muse, mutect2, varscan2
- MDGA2 | c.2172A>G p.L724= (on ENST00000399232 / NM_001113498.2; = p.L426= on NM_182830.4) | Silent (SNP) | VAF 13/151 reads (9%) | catalogued as rs1265342645; called by muse, mutect2
- MED14 | c.1542G>T p.T514= | Silent (SNP) | VAF 62/109 reads (57%) | called by muse, mutect2, varscan2
- MLH3 | c.3027A>G p.V1009= | Silent (SNP) | VAF 74/394 reads (19%) | called by muse, mutect2, varscan2
- MUC17 | c.3399C>G p.T1133= | Silent (SNP) | VAF 33/257 reads (13%) | called by muse, mutect2, varscan2
- MYH8 | c.3990C>T p.N1330= | Silent (SNP) | VAF 44/478 reads (9%) | catalogued as rs199830005, COSV67963296; called by muse, mutect2
- NBPF9 | c.2796G>C p.L932= | Silent (SNP) | VAF 82/511 reads (16%) | catalogued as rs1553648636; called by muse, mutect2, varscan2
- NCL | c.2022A>T p.G674= | Silent (SNP) | VAF 81/349 reads (23%) | called by muse, mutect2, varscan2
- NHLH1 | c.159T>A p.P53= | Silent (SNP) | VAF 89/381 reads (23%) | called by muse, varscan2
- NLRP5 | c.828C>A p.G276= | Silent (SNP) | VAF 51/264 reads (19%) | called by muse, mutect2, varscan2
- NOMO1 | c.2046G>T p.V682= | Silent (SNP) | VAF 12/47 reads (26%) | called by mutect2, varscan2
- OAS2 | c.1269C>T p.S423= | Silent (SNP) | VAF 48/440 reads (11%) | catalogued as COSV100660015; called by muse, mutect2, varscan2
- OR11H6 | c.192C>A p.V64= | Silent (SNP) | VAF 29/179 reads (16%) | called by muse, mutect2, varscan2
- OR2G2 | c.750G>A p.V250= | Silent (SNP) | VAF 27/263 reads (10%) | catalogued as COSV60740737; called by muse, mutect2, varscan2
- OR5W2 | c.864G>T p.L288= | Silent (SNP) | VAF 20/185 reads (11%) | catalogued as COSV60617506; called by muse, mutect2, varscan2
- OR8H2 | c.690C>G p.S230= | Silent (SNP) | VAF 36/205 reads (18%) | catalogued as COSV57944695; called by muse, mutect2, varscan2
- OR8K5 | c.60G>T p.R20= | Silent (SNP) | VAF 31/157 reads (20%) | called by muse, mutect2, varscan2
- PCDH10 | c.1458C>T p.S486= | Silent (SNP) | VAF 19/179 reads (11%) | catalogued as rs748097682; called by muse, mutect2, varscan2
- PCDHA7 | c.2094G>C p.V698= | Silent (SNP) | VAF 39/351 reads (11%) | catalogued as COSV65334813; called by muse, mutect2, varscan2
- PCDHB4 | c.151C>T p.L51= | Silent (SNP) | VAF 58/231 reads (25%) | called by muse, mutect2, varscan2
- PCDHB5 | c.2025G>T p.A675= | Silent (SNP) | VAF 73/370 reads (20%) | called by muse, mutect2, varscan2
- PCDHB8 | c.1743C>A p.A581= | Silent (SNP) | VAF 62/1787 reads (3%) | called by muse, mutect2
- PCDHGB4 | c.771G>T p.P257= | Silent (SNP) | VAF 70/240 reads (29%) | called by muse, mutect2, varscan2
- PEG3 | c.4323A>T p.G1441= | Silent (SNP) | VAF 73/359 reads (20%) | called by muse, mutect2, varscan2
- PIWIL1 | c.1014T>A p.S338= | Silent (SNP) | VAF 42/178 reads (24%) | called by muse, mutect2, varscan2
- PLEKHA3 | c.573G>T p.P191= | Silent (SNP) | VAF 31/146 reads (21%) | called by muse, mutect2, varscan2
- PNMA8B | c.1626C>A p.P542= | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- PPARGC1A | c.2133G>C p.R711= | Silent (SNP) | VAF 33/173 reads (19%) | called by muse, mutect2, varscan2
- PRND | c.466C>A p.R156= | Silent (SNP) | VAF 83/185 reads (45%) | catalogued as COSV59896088; called by muse, mutect2, varscan2
- PRRT4 | c.1290G>A p.A430= | Silent (SNP) | VAF 28/378 reads (7%) | catalogued as rs1304534400; called by muse, mutect2
- PTPRT | c.1785C>T p.D595= | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as rs1161402032; called by muse, mutect2, varscan2
- QSER1 | c.2253T>G p.S751= (on ENST00000399302; = p.S880= on NM_001076786.3) | Silent (SNP) | VAF 43/180 reads (24%) | called by muse, mutect2, varscan2
- RELN | c.1407C>A p.T469= | Silent (SNP) | VAF 121/356 reads (34%) | catalogued as COSV100633309; called by muse, varscan2
- REN | c.360C>A p.L120= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, varscan2
- ROBO4 | c.672C>A p.S224= | Silent (SNP) | VAF 48/124 reads (39%) | catalogued as COSV60628492; called by muse, mutect2, varscan2
- SCAMP5 | c.441G>T p.S147= | Silent (SNP) | VAF 18/149 reads (12%) | called by muse, mutect2, varscan2
- SEC16B | c.1107C>T p.L369= | Silent (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- SERPINA6 | c.57C>A p.T19= | Silent (SNP) | VAF 53/273 reads (19%) | catalogued as COSV104419917, COSV58585988; called by muse, mutect2, varscan2
- SEZ6L2 | c.486T>A p.T162= (on ENST00000308713 / NM_001114099.3; = p.T92= on NM_012410.4) | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as COSV58098599; called by muse, mutect2, varscan2
- SH3BP4 | c.2658G>A p.V886= | Silent (SNP) | VAF 20/84 reads (24%) | called by muse, varscan2
- SIGLEC6 | c.564C>A p.T188= | Silent (SNP) | VAF 70/240 reads (29%) | catalogued as rs367754296; called by muse, mutect2, varscan2
- SLC17A6 | c.1146G>C p.T382= | Silent (SNP) | VAF 15/105 reads (14%) | called by muse, mutect2, varscan2
- SLC22A9 | c.1305T>A p.R435= | Silent (SNP) | VAF 47/170 reads (28%) | called by muse, mutect2, varscan2
- SNTG1 | c.1035C>G p.L345= | Silent (SNP) | VAF 107/206 reads (52%) | catalogued as COSV52474775, COSV99383845; called by muse, mutect2, varscan2
- SPAG6 | c.339T>C p.H113= | Silent (SNP) | VAF 27/179 reads (15%) | catalogued as COSV100509947; called by muse, mutect2, varscan2
- SPINK6 | c.231T>A p.P77= | Silent (SNP) | VAF 20/194 reads (10%) | catalogued as rs866331106; called by muse, mutect2
- ST8SIA5 | c.495T>A p.A165= | Silent (SNP) | VAF 67/266 reads (25%) | called by muse, mutect2, varscan2
- SYNE2 | c.16737G>T p.T5579= | Silent (SNP) | VAF 125/508 reads (25%) | catalogued as rs147156341; called by muse, mutect2, varscan2
- TCHH | c.1482G>A p.E494= | Silent (SNP) | VAF 22/374 reads (6%) | catalogued as rs1348163121; called by muse, mutect2
- TEK | c.2736C>T p.D912= | Silent (SNP) | VAF 119/516 reads (23%) | called by muse, mutect2, varscan2
- THBS2 | c.2286C>T p.P762= | Silent (SNP) | VAF 16/169 reads (9%) | called by muse, mutect2, varscan2
- TIMM21 | c.405A>T p.S135= | Silent (SNP) | VAF 34/143 reads (24%) | called by muse, mutect2, varscan2
- TLX3 | c.471C>A p.P157= | Silent (SNP) | VAF 47/224 reads (21%) | called by muse, mutect2, varscan2
- TMEM270 | c.666G>T p.T222= | Silent (SNP) | VAF 96/357 reads (27%) | catalogued as COSV100260424, COSV57640071; called by muse, mutect2, varscan2
- TNN | c.3081G>A p.A1027= | Silent (SNP) | VAF 39/294 reads (13%) | catalogued as rs368089539; called by muse, mutect2, varscan2
- TRAIP | c.582G>A p.V194= | Silent (SNP) | VAF 20/161 reads (12%) | called by muse, mutect2, varscan2
- TRIM51GP | c.282G>T p.G94= | Silent (SNP) | VAF 53/311 reads (17%) | called by muse, mutect2, varscan2
- TSPAN7 | c.375G>T p.T125= | Silent (SNP) | VAF 129/234 reads (55%) | called by muse, mutect2, varscan2
- TSPYL6 | c.1218G>A p.G406= | Silent (SNP) | VAF 12/94 reads (13%) | called by muse, varscan2
- TTN | c.81120C>A p.A27040= (on ENST00000591111; = p.A19616= on NM_003319.4) | Silent (SNP) | VAF 66/196 reads (34%) | catalogued as rs931824826, COSV59988918; ClinVar: likely benign; called by mutect2, varscan2
- UMOD | c.1908C>A p.T636= | Silent (SNP) | VAF 92/413 reads (22%) | catalogued as rs369335930; called by muse, mutect2, varscan2
- UNKL | c.1110G>T p.A370= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs752481903; called by muse, mutect2, varscan2
- VENTX | c.156C>A p.S52= | Silent (SNP) | VAF 42/189 reads (22%) | called by muse, mutect2, varscan2
- WDFY4 | c.3645T>C p.Y1215= | Silent (SNP) | VAF 70/301 reads (23%) | called by muse, mutect2, varscan2
- WNT6 | c.381C>A p.G127= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as rs764769863; called by muse, mutect2
- ZNF180 | c.1896A>C p.P632= | Silent (SNP) | VAF 23/186 reads (12%) | called by muse, mutect2, varscan2
- ZSCAN4 | c.336C>A p.G112= | Silent (SNP) | VAF 28/120 reads (23%) | called by muse, varscan2
- ABCB4 | c.*8C>A | 3'UTR (SNP) | VAF 108/302 reads (36%) | called by muse, mutect2, varscan2
- AC009093.9 | chr16:29075013 G>T | 5'Flank (SNP) | VAF 39/158 reads (25%) | called by muse, mutect2, varscan2
- AC011410.1 | n.580C>A | RNA (SNP) | VAF 39/123 reads (32%) | called by muse, mutect2, varscan2
- AC073648.1 | n.650C>T | RNA (SNP) | VAF 16/185 reads (9%) | called by muse, mutect2
- ACAD8 | c.940-67G>T | Intron (SNP) | VAF 110/334 reads (33%) | called by muse, mutect2, varscan2
- ACTN1 | c.105+968G>T | Intron (SNP) | VAF 40/212 reads (19%) | called by muse, mutect2, varscan2
- ACTN1 | c.105+967G>T | Intron (SNP) | VAF 40/217 reads (18%) | called by muse, mutect2, varscan2
- ADGRA1 | chr10:133085031 G>C | 5'Flank (SNP) | VAF 42/152 reads (28%) | catalogued as COSV100811016; called by muse, mutect2, varscan2
- AGAP12P | n.1184C>A | RNA (SNP) | VAF 59/676 reads (9%) | called by muse, mutect2
- AL353804.7 | chrX:73845711 A>G | 5'Flank (SNP) | VAF 113/194 reads (58%) | called by muse, mutect2, varscan2
- AL772337.1 | n.854G>T | RNA (SNP) | VAF 55/269 reads (20%) | called by muse, mutect2, varscan2
- APEX1 | c.58+75G>A | Intron (SNP) | VAF 30/285 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP25 | c.*46T>C | 3'UTR (SNP) | VAF 53/344 reads (15%) | called by muse, mutect2, varscan2
- ARHGAP27 | c.658-4119G>T | Intron (SNP) | VAF 44/143 reads (31%) | called by muse, mutect2, varscan2
- ATR | c.7193-51C>T | Intron (SNP) | VAF 38/144 reads (26%) | called by muse, varscan2
- BCAS3 | c.2075-4836G>T | Intron (SNP) | VAF 74/345 reads (21%) | called by muse, mutect2, varscan2
- BHLHE22 | chr8:64576274 C>G | 5'Flank (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2, varscan2
- C16orf87 | c.66+31G>T | Intron (SNP) | VAF 13/138 reads (9%) | called by muse, mutect2
- CAPN11 | c.16+2975G>T | Intron (SNP) | VAF 38/207 reads (18%) | called by muse, mutect2, varscan2
- CBLB | c.2202-9G>C | Intron (SNP) | VAF 26/212 reads (12%) | called by muse, mutect2, varscan2
- CCDC148 | c.1110+20618C>A | Intron (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- CCDC162P | n.1813-2664G>T | Intron (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2, varscan2
- CCDC47 | c.1371+64G>C | Intron (SNP) | VAF 63/223 reads (28%) | called by muse, mutect2, varscan2
- CCM2 | c.*116G>C | 3'UTR (SNP) | VAF 26/163 reads (16%) | called by muse, mutect2, varscan2
- CCNYL2 | n.624-2552C>A | Intron (SNP) | VAF 48/275 reads (17%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*2171C>A | 3'UTR (SNP) | VAF 89/353 reads (25%) | called by muse, varscan2
- CNTLN | c.449+23493del | Intron (DEL) | VAF 10/132 reads (8%) | called by mutect2, pindel
- DCHS2 | n.4194G>T | RNA (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2, varscan2
- DDX49 | c.448-14C>T | Intron (SNP) | VAF 40/179 reads (22%) | called by muse, mutect2, varscan2
- DENND3 | c.956+2225A>G | Intron (SNP) | VAF 32/316 reads (10%) | called by muse, mutect2
- DENND3 | c.956+2226A>T | Intron (SNP) | VAF 34/318 reads (11%) | called by muse, mutect2
- DPP6 | c.*265C>A | 3'UTR (SNP) | VAF 36/182 reads (20%) | called by muse, mutect2, varscan2
- DTWD1 | c.265-1216G>C | Intron (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- EMBP1 | n.950A>T | RNA (SNP) | VAF 25/226 reads (11%) | called by muse, mutect2, varscan2
- FHL1 | c.-26-9574G>C | Intron (SNP) | VAF 57/90 reads (63%) | called by muse, mutect2, varscan2
- FLT4 | c.3807+46G>T | Intron (SNP) | VAF 38/132 reads (29%) | called by muse, mutect2, varscan2
- GNAS | c.2068+293G>T | Intron (SNP) | VAF 56/176 reads (32%) | called by muse, mutect2, varscan2
- GRM6 | c.2125-14G>C | Intron (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- GTPBP3 | c.*2G>A | 3'UTR (SNP) | VAF 4/28 reads (14%) | catalogued as rs1235142541, COSV100259014, COSV61413054; called by muse, mutect2
- GUSBP10 | n.112G>T | RNA (SNP) | VAF 28/159 reads (18%) | called by muse, mutect2, varscan2
- GUSBP10 | n.111G>C | RNA (SNP) | VAF 29/160 reads (18%) | called by muse, mutect2, varscan2
- GVINP1 | n.3273C>A | RNA (SNP) | VAF 21/244 reads (9%) | called by muse, mutect2
- HDAC6 | c.*301G>T | 3'UTR (SNP) | VAF 59/105 reads (56%) | called by muse, mutect2, varscan2
- IBA57 | chr1:228164266 C>A | 5'Flank (SNP) | VAF 86/422 reads (20%) | called by muse, mutect2, varscan2
- IL7R | c.801-97T>A | Intron (SNP) | VAF 55/231 reads (24%) | called by muse, mutect2, varscan2
- KALRN | c.7377+112G>T | Intron (SNP) | VAF 24/145 reads (17%) | called by muse, mutect2, varscan2
- KCNA1 | c.-11C>T | 5'UTR (SNP) | VAF 12/222 reads (5%) | catalogued as rs1211621955; called by muse, mutect2
- KIR3DX1 | n.1032C>G | RNA (SNP) | VAF 55/201 reads (27%) | called by muse, mutect2, varscan2
- LEXM | chr1:54806079 C>T | 5'Flank (SNP) | VAF 7/67 reads (10%) | catalogued as rs1446800572; called by muse, mutect2
- LINC02253 | n.488-13452C>A | Intron (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
- LINC02551 | n.996C>T | RNA (SNP) | VAF 46/158 reads (29%) | called by muse, mutect2, varscan2
- LRRC37A17P | n.3956G>A | RNA (SNP) | VAF 33/364 reads (9%) | catalogued as rs753525298; called by muse, mutect2, varscan2
- LTN1 | chr21:28992915 G>T | 5'Flank (SNP) | VAF 27/100 reads (27%) | called by muse, mutect2, varscan2
- MAST2 | c.500+35056A>G | Intron (SNP) | VAF 23/226 reads (10%) | called by muse, mutect2, varscan2
- MBD1 | c.793-139G>C | Intron (SNP) | VAF 38/149 reads (26%) | catalogued as COSV54002537; called by muse, mutect2, varscan2
- MEIS3 | c.13-146G>T | Intron (SNP) | VAF 36/103 reads (35%) | called by muse, mutect2, varscan2
- MIR1208 | n.13C>A | RNA (SNP) | VAF 39/519 reads (8%) | called by muse, mutect2
- MIR520D | n.2C>G | RNA (SNP) | VAF 16/197 reads (8%) | called by muse, mutect2
- MUC19 | chr12:40545066 A>C | 3'Flank (SNP) | VAF 58/244 reads (24%) | called by muse, mutect2, varscan2
- MYPN | c.*677T>A | 3'UTR (SNP) | VAF 151/586 reads (26%) | called by muse, mutect2, varscan2
- NTRK3 | c.1586-40581G>T | Intron (SNP) | VAF 74/318 reads (23%) | catalogued as COSV100446255; called by muse, mutect2, varscan2
- OR2M1P | n.628C>G | RNA (SNP) | VAF 33/532 reads (6%) | called by muse, mutect2
- OVCH1 | c.893-582G>T | Intron (SNP) | VAF 41/161 reads (25%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-67010G>A | Intron (SNP) | VAF 49/217 reads (23%) | catalogued as rs1194658203, COSV99338078; called by muse, mutect2, varscan2
- PDE2A | c.72-15787C>A | Intron (SNP) | VAF 43/244 reads (18%) | called by muse, mutect2, varscan2
- PDE4B | c.477-207G>T | Intron (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- POM121L4P | n.1228G>T | RNA (SNP) | VAF 145/527 reads (28%) | called by muse, mutect2, varscan2
- PTAR1 | c.86+1168T>G | Intron (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2, varscan2
- RBM38 | c.416+6633G>T | Intron (SNP) | VAF 42/258 reads (16%) | called by muse, mutect2, varscan2
- REG1B | c.433+57G>A | Intron (SNP) | VAF 42/172 reads (24%) | called by muse, varscan2
- RHD | c.-21C>A | 5'UTR (SNP) | VAF 28/221 reads (13%) | called by muse, mutect2, varscan2
- RIMS1 | c.1679-20615G>T | Intron (SNP) | VAF 19/147 reads (13%) | catalogued as rs972698038; called by muse, mutect2, varscan2
- RIMS2 | c.3821+1027A>T | Intron (SNP) | VAF 133/254 reads (52%) | called by muse, mutect2, varscan2
- RYR2 | c.11146-1227C>A | Intron (SNP) | VAF 16/166 reads (10%) | called by muse, mutect2
- SBF1 | c.*317_*318dup | 3'UTR (INS) | VAF 14/101 reads (14%) | catalogued as rs757983848; called by mutect2, pindel, varscan2
- SERP2 | c.-25G>A | 5'UTR (SNP) | VAF 52/293 reads (18%) | called by muse, mutect2, varscan2
- SLC51A | chr3:196214492 C>G | 5'Flank (SNP) | VAF 20/165 reads (12%) | called by muse, mutect2, varscan2
- SLC6A13 | c.*39G>T | 3'UTR (SNP) | VAF 52/185 reads (28%) | called by muse, mutect2, varscan2
- SLC6A13 | c.*38T>A | 3'UTR (SNP) | VAF 54/191 reads (28%) | called by muse, mutect2, varscan2
- SLCO4A1 | chr20:62642047 C>A | 5'Flank (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- SPAG9 | c.590+765G>T | Intron (SNP) | VAF 18/232 reads (8%) | catalogued as COSV56236778; called by muse, mutect2
- TADA2A | c.823+26G>T | Intron (SNP) | VAF 41/217 reads (19%) | called by muse, mutect2, varscan2
- TADA3 | c.565-427C>G | Intron (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2, varscan2
- TMBIM6 | c.-31+649G>T | Intron (SNP) | VAF 29/107 reads (27%) | catalogued as COSV99920885; called by muse, mutect2, varscan2
- TPRX2P | n.799C>A | RNA (SNP) | VAF 57/200 reads (29%) | catalogued as rs1299893318; called by muse, mutect2, varscan2
- TRAF3 | c.820-2134G>T | Intron (SNP) | VAF 18/136 reads (13%) | catalogued as rs982275159; called by muse, mutect2, varscan2
- TYK2 | c.3028-46C>A | Intron (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
- UGT2A1 | c.715+11168del | Intron (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel
- UMPS | c.*4507G>T | 3'UTR (SNP) | VAF 36/245 reads (15%) | called by muse, mutect2, varscan2
- ZNF347 | c.16-34T>C | Intron (SNP) | VAF 18/186 reads (10%) | called by muse, mutect2, varscan2
- ZNF43 | c.-49T>G | 5'UTR (SNP) | VAF 27/135 reads (20%) | called by muse, mutect2, varscan2
- ZNF487 | c.*1011G>T | 3'UTR (SNP) | VAF 55/239 reads (23%) | called by muse, mutect2, varscan2
- ZNF606 | chr19:58004363 A>T | 5'Flank (SNP) | VAF 50/136 reads (37%) | called by muse, mutect2, varscan2
- ZNF849P | n.887G>T | RNA (SNP) | VAF 73/445 reads (16%) | called by muse, mutect2, varscan2
